Surgical pathology report (de-identified scan), TCGA case TCGA-C5-A7XC, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Medical College of Wisconsin, specimen TCGA-C5-A7XC-01A (Primary Tumor).

SURGICAL PATHOLOGY REPORT - CONSULT

Patient Name: [REDACTED]

Address: [REDACTED]

Service: [REDACTED]

Location: [REDACTED]

Accession #: [REDACTED]

Received: [REDACTED]

Gender: F

DOB: [REDACTED]

(Age: [REDACTED])

MRN: [REDACTED]

Hospital #: [REDACTED]

Patient Type: [REDACTED]

Reported: [REDACTED]

Physician(s): [REDACTED] M.D.

ICD-O-3
Carcinoma, squamous cell NOS
8070/3
Site Cervix NOS
C53.9
Endocervix C53.0
9/10/13

DIAGNOSIS

CERVIX, BIOPSY ([REDACTED])

- INVASIVE, MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA (SEE COMMENT)

ENDOCERVIX, CURETTAGE ([REDACTED])

- STRIPS AND FRAGMENTS OF BENIGN ENDOCERVICAL AND ENDOMETRIAL TISSUE
- NO DYSPLASIA OR CARCINOMA IDENTIFIED

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

[REDACTED] M.D.

***Report Electronically Reviewed and Signed Out By [REDACTED]

[REDACTED] M.D.***

Microscopic Description and Comment

Sections [REDACTED] and 2, two slides, from [REDACTED] are seen in consultation. Sections of the cervix show moderately differentiated invasive squamous cell carcinoma. The surface epithelium has full thickness dysplasia extending extensively into the endocervical glands. In at least one area, the neoplasm invades as small, irregular nests into the underlying stroma which exhibits a desmoplastic reaction. A depth of invasion cannot be provided in these randomly oriented fragments of tissue. No lymphovascular space invasion is appreciated. The endocervical curettage is free of dysplasia and invasive carcinoma. [REDACTED]

[REDACTED] M.D.

History

The patient is a [REDACTED] year old female with a Pap smear on [REDACTED] showing high grade SIL.

Material(s) Received

Received are two slides labeled [REDACTED] and sublabeled 1 and 2. These are derived from a cervical biopsy and endocervical curettage performed on [REDACTED] as detailed in the accompanying corresponding pathology report. The material originates from [REDACTED]

Physician Copy [REDACTED]

Source: NCI Genomic Data Commons file 9673aba7-e885-4fad-aea9-c0dc25ac0301 (TCGA-C5-A7XC.5BE71CCD-AA13-4B9E-BD99-2122F9A00B3A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).